MMRF case MMRF_2362 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/136f3992-fd0d-42d9-9061-6fdad29d13ff

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.0 years (23,754 days); ISS stage: II; Days to last known disease status: 729 days (2.0 years); Days to last follow up: 729 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 3): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 32.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.84 mg/dL; Beta 2 Microglobulin 3.09 µg/mL; Lactate Dehydrogenase 5.23 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 11 ×10⁹/L; Absolute Neutrophil 8.6 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 1.79 mmol/L; Calcium 2.53 mmol/L; Albumin 31 g/L; Glucose 4.9 mmol/L.
- Day 99 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 6.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.6 mg/dL; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.45 mmol/L; Albumin 36 g/L; Total Protein 6 g/dL; Glucose 6.11 mmol/L.
- Day 190 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 3.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.38 mg/dL; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 5.06 mmol/L.
- Day 274 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 5.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.33 mg/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 1.92 g/L; Immunoglobulin M 0.46 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.55 mmol/L; Albumin 35 g/L; Total Protein 6.5 g/dL; Glucose 4.84 mmol/L.
- Day 351 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 11.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.95 mg/dL; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 1.79 mmol/L; Calcium 2.35 mmol/L; Albumin 32 g/L; Total Protein 6.2 g/dL; Glucose 5.56 mmol/L.
- Day 463 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.49 mg/dL; Lactate Dehydrogenase 3.75 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.1 mmol/L; Albumin 26 g/L; Total Protein 5.3 g/dL; Glucose 7.15 mmol/L.
- Day 631: Serum Free Immunoglobulin Light Chain, Kappa 3.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.41 mg/dL; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.25 mmol/L; Albumin 28 g/L; Total Protein 5.8 g/dL; Glucose 9.02 mmol/L.
- Day 729: Serum Free Immunoglobulin Light Chain, Kappa 2.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.14 mg/dL; Lactate Dehydrogenase 6.38 µkat/L; Hemoglobin 9.49 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 31 g/L; Total Protein 5.7 g/dL; Glucose 4.57 mmol/L.

Other clinical attributes
- Day 1: Weight: 78 kg; Height: 172 cm.

Biospecimens (2 samples)
- Sample MMRF_2362_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2362_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
